Gene-level copy-number profile of tumor specimen C3L-00905-02 from CPTAC case C3L-00905, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 65.0 years (23,742 days).
Specimen C3L-00905-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b38731d-6c19-4a1e-93e1-8113b614d3b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00905-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/a8e92311-3d34-4834-a9af-a6e77d8a1f1a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 11; copy number 2: 2,374; copy number 3: 140; copy number 4: 27,935; copy number 5: 1,873; copy number 6: 17,718; copy number 7: 2,610; copy number 8: 2,802; copy number 9: 1,018; copy number 10: 644; copy number 12: 396; copy number 13: 94; copy number 14: 177; copy number 15: 128; copy number 16: 85; copy number 17: 65; copy number 18: 167; copy number 19: 107; copy number 21: 13; copy number 24: 9; copy number 30: 13.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:32,313,126–32,403,292, 5 genes: AC139426.1, AC139426.2, DNM1P31, GOLGA8K, RN7SL185P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,916 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,154,761–37,325,100, 1 gene, copy number 12 (within-gene range 4–12): AL353604.1.
- chr1:37,330,852–47,550,753, 350 genes, copy number 9–13 (broad region; genes not listed).
- chr1:201,829,149–201,946,588, 5 genes, copy number 10 (within-gene range 6–10): IPO9, MIR6739, SHISA4, AL513217.1, LMOD1.
- chr1:204,218,853–204,377,665, 2 genes, copy number 10 (within-gene range 6–10): PLEKHA6, AL592114.3.
- chr1:204,822,664–206,102,449, 41 genes, copy number 10: AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3.
- chr1:206,928,522–207,144,972, 8 genes, copy number 10: PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3.
- chr1:212,035,553–212,107,400, 4 genes, copy number 10: DTL, RPL21P28, MIR3122, RN7SKP98.
- chr2:189,311,263–242,175,634, 986 genes, copy number 9 (broad region; genes not listed).
- chr4:2,536,647–2,732,573, 1 gene, copy number 21 (within-gene range 4–21): FAM193A.
- chr4:2,741,648–3,040,760, 8 genes, copy number 21: TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4.
- chr6:105,919–8,102,559, 168 genes, copy number 9–10 (broad region; genes not listed).
- chr8:59,137,372–59,893,942, 8 genes, copy number 10: AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1.
- chr8:71,675,300–93,819,234, 315 genes, copy number 10–17 (broad region; genes not listed).
- chr8:94,637,285–105,804,539, 222 genes, copy number 12–16 (within-gene range 6–16) (broad region; genes not listed).
- chr8:144,529,179–145,006,046, 21 genes, copy number 9: ARHGAP39, AC084125.3, Metazoa_SRP, AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2.
- chr9:39,886,861–40,122,540, 5 genes, copy number 10–13: RN7SL763P, SNORA70, CR769767.1, AL773545.3, CDRT15P14.
- chr10:61,406,642–62,096,944, 6 genes, copy number 16–21: TMEM26, TMEM26-AS1, CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr10:84,003,332–87,863,533, 79 genes, copy number 10–18 (within-gene range 2–18) (broad region; genes not listed).
- chr11:65,145,691–71,252,577, 271 genes, copy number 10–19 (broad region; genes not listed).
- chr12:38,532,895–39,170,880, 8 genes, copy number 10: AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1.
- chr12:42,069,935–43,806,328, 35 genes, copy number 10: AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr12:56,118,250–56,144,674, 1 gene, copy number 17 (within-gene range 8–17): ESYT1.
- chr12:56,150,796–56,596,193, 33 genes, copy number 17 (within-gene range 8–17): AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P.
- chr12:63,002,469–68,234,686, 115 genes, copy number 10–24 (broad region; genes not listed).
- chr13:69,408,216–78,286,288, 96 genes, copy number 10 (broad region; genes not listed).
- chr14:105,209,286–105,315,589, 2 genes, copy number 9 (within-gene range 6–9): BRF1, BTBD6.
- chr15:24,954,986–26,949,208, 115 genes, copy number 18–30 (within-gene range 6–30) (broad region; genes not listed).
- chr17:36,225,246–36,457,535, 10 genes, copy number 10–15: AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, TBC1D3F, TBC1D3J.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
